Somatic mutation profile of tumor specimen C3N-00337-03 (aliquot CPT0018960006) from CPTAC case C3N-00337, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.1 years (24,501 days).
Specimen C3N-00337-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b8a8c98-f403-47c3-bf14-fd3486c42ddc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00337-31 (Blood Derived Normal), aliquot CPT0019100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5134e37a-57cd-408a-9726-7e470d8584b4

The open-access MAF lists 83 somatic variants for this specimen: 52 protein-altering or splice-affecting, 18 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 18, Intron 7, Nonsense Mutation 4, Splice Site 4, In Frame Del 2, Frame Shift Ins 2, 5'Flank 2, 3'UTR 2, Splice Region 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 183/484 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CACNA1C | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs587782933, CM057538; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 104/179 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 108/202 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 219/269 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATAD1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 93/452 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs1422620549, COSV57756748; called by muse, mutect2, varscan2
- B3GALT4 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 103/181 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs1226660769; called by muse, mutect2, varscan2
- C10orf71 | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 236/395 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs373861853, COSV60506335; called by muse, mutect2, varscan2
- C1QTNF8 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375547605; called by muse, mutect2, varscan2
- CEP78 | c.1585C>T p.Q529* (on ENST00000424347 / NM_001349840.2; = p.Q530* on NM_032171.3) | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as rs748298025; called by muse, mutect2, varscan2
- CERS3 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99432499; called by muse, mutect2, varscan2
- CHD4 | c.3992A>G p.N1331S (on ENST00000357008 / NM_001363606.2; = p.N1344S on NM_001273.5) | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs76527521; called by muse, mutect2, varscan2
- CLK1 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 42/103 reads (41%) | catalogued as COSV58432616; called by muse, mutect2, varscan2
- DHRS13 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1485008987, COSV60454270; called by muse, mutect2, varscan2
- DLGAP2 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747241484, COSV101421836, COSV70099801; called by muse, mutect2, varscan2
- EIF2AK3 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 32/385 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745376249; called by muse, mutect2
- FAM199X | c.468A>G p.I156M | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs868970547, COSV100245572; called by muse, mutect2, varscan2
- FURIN | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs149616063; called by muse, mutect2, varscan2
- GJB1 | c.483del p.M162Wfs*34 | Frame Shift Del (DEL) | VAF 74/194 reads (38%) | catalogued as HM070062, COSV100661292; called by mutect2, pindel, varscan2
- HNRNPL | c.1010dup p.P338Tfs*56 | Frame Shift Ins (INS) | VAF 24/49 reads (49%) | catalogued as rs767148651; called by mutect2, varscan2
- LRRC63 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs187668310, COSV101115815; called by muse, mutect2, varscan2
- MADD | c.4595G>A p.R1532Q | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV60630098; called by muse, mutect2, varscan2
- MYO1F | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 127/523 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs778366731; called by muse, mutect2, varscan2
- NRXN3 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780696301, COSV59719290; called by muse, varscan2
- PLCL1 | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559099836, COSV70821454, COSV70821834; called by muse, mutect2
- TBR1 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343611259; called by muse, mutect2
- TNFAIP2 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 47/136 reads (35%) | catalogued as rs760095105, COSV100280909; called by muse, mutect2, varscan2
- TPMT | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as rs772470049; called by muse, mutect2, varscan2
- TTBK1 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs374064146; called by muse, mutect2, varscan2
- UNC13D | c.756C>T p.D252= | Splice Region (SNP) | VAF 72/197 reads (37%) | catalogued as rs764298899; called by muse, mutect2, varscan2
- ZNF232 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 104/326 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs199538285; called by muse, mutect2, varscan2
- A2M | c.3739G>A p.G1247S | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS9 | c.3556_3558del p.W1186del | In Frame Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- ARMH3 | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 87/151 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ATXN7L3 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- BCAT1 | c.1040_1044+7del p.X347_splice | Splice Site (DEL) | VAF 11/91 reads (12%) | called by mutect2, pindel
- BRD1 | c.1971_1973delinsG p.D657Efs*28 | Frame Shift Del (DEL) | VAF 56/212 reads (26%) | called by pindel, varscan2*
- DAPP1 | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- DST | c.10939G>T p.E3647* (on ENST00000361203 / NM_001374722.1; = p.E1235* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 34/55 reads (62%) | called by muse, mutect2, varscan2
- GLT1D1 | c.959T>A p.V320E (on ENST00000442111 / NM_001366889.1; = p.V240E on NM_144669.3) | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- KCND1 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM7A | c.1337_1338+1del p.X446_splice | Splice Site (DEL) | VAF 21/42 reads (50%) | called by pindel, varscan2
- KRT32 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MAVS | c.1021C>T p.L341F | Missense Mutation (SNP) | VAF 152/472 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MCM7 | c.2062G>T p.G688C | Missense Mutation (SNP) | VAF 323/609 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3CA | c.308_316del p.E103_V105del | In Frame Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- RBM39 | c.1225+3_1225+17del | Splice Region (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- TLK2 | c.1188-4_1190del p.X396_splice (on ENST00000326270 / NM_001284333.2; = p.X374_splice on NM_006852.6 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- XRN1 | c.4573G>T p.A1525S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFYVE16 | c.2337_2338insA p.C780Mfs*3 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- ZNF280C | c.664+1G>T p.X222_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | called by muse, varscan2
- C4A | c.2757C>T p.F919= | Silent (SNP) | VAF 227/2346 reads (10%) | catalogued as rs529197965, COSV71178556; called by muse, mutect2
- C4B | c.2757C>T p.F919= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1274822802; called by mutect2, varscan2
- CASS4 | c.867C>T p.S289= | Silent (SNP) | VAF 63/168 reads (38%) | called by muse, mutect2, varscan2
- D2HGDH | c.903G>A p.G301= | Silent (SNP) | VAF 133/515 reads (26%) | called by muse, mutect2, varscan2
- EHF | c.246C>T p.G82= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as rs1394818945; called by muse, mutect2, varscan2
- GDF7 | c.732G>A p.P244= | Silent (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- KCNC3 | c.1791G>A p.P597= | Silent (SNP) | VAF 43/158 reads (27%) | catalogued as rs755920393; called by muse, mutect2, varscan2
- KRT28 | c.828C>T p.D276= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as rs745406486, COSV60685678; called by muse, mutect2, varscan2
- LRRC14B | c.1005G>T p.V335= | Silent (SNP) | VAF 37/293 reads (13%) | called by muse, mutect2, varscan2
- MEX3B | c.1008C>T p.N336= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs921880386; called by muse, mutect2, varscan2
- MIDEAS | c.186G>T p.V62= | Silent (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- MOGAT1 | c.225C>A p.I75= | Silent (SNP) | VAF 40/172 reads (23%) | called by muse, mutect2, varscan2
- RORA | c.1500A>G p.R500= (on ENST00000335670 / NM_134261.3; = p.R525= on NM_002943.3) | Silent (SNP) | VAF 30/101 reads (30%) | called by muse, mutect2, varscan2
- SH2D5 | c.1194G>A p.G398= (on ENST00000444387 / NM_001103161.2; = p.G314= on NM_001103160.2) | Silent (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- SLC23A3 | c.831T>G p.V277= | Silent (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- TMEM248 | c.246C>T p.T82= | Silent (SNP) | VAF 94/384 reads (24%) | catalogued as rs746836640; called by muse, mutect2, varscan2
- UGT3A2 | c.1344G>A p.P448= | Silent (SNP) | VAF 68/329 reads (21%) | catalogued as rs748443933, COSV56929498; called by muse, mutect2, varscan2
- ZBTB47 | c.1242G>A p.S414= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs747312307; called by muse, mutect2, varscan2
- C11orf21 | c.54-157A>G | Intron (SNP) | VAF 79/192 reads (41%) | catalogued as rs1160998421; called by muse, mutect2, varscan2
- CHRNA4 | c.*58C>T | 3'UTR (SNP) | VAF 320/852 reads (38%) | catalogued as rs202156992; called by muse, mutect2, varscan2
- CNGB1 | c.*50C>T | 3'UTR (SNP) | VAF 94/213 reads (44%) | catalogued as rs1567358700, COSV99201449; called by muse, mutect2, varscan2
- CYGB | chr17:76538507 G>A | 5'Flank (SNP) | VAF 42/128 reads (33%) | called by muse, mutect2, varscan2
- EIF3L | c.-40C>G | 5'UTR (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- MAZ | c.1280-393del | Intron (DEL) | VAF 7/32 reads (22%) | catalogued as COSV50715373; called by mutect2, pindel
- MOV10L1 | c.3216+18A>C | Intron (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- PQBP1 | c.179+247G>A | Intron (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- SCIN | chr7:12570553 C>A | 5'Flank (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2
- SEC1P | n.957G>A | RNA (SNP) | VAF 89/167 reads (53%) | catalogued as rs776799749; called by muse, mutect2, varscan2
- SEMA4C | c.110-252G>A | Intron (SNP) | VAF 12/62 reads (19%) | catalogued as rs1301299397; called by muse, mutect2
- SHANK2 | c.1174+32665C>G | Intron (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- TNFRSF1B | c.308-9C>T | Intron (SNP) | VAF 85/259 reads (33%) | called by muse, mutect2, varscan2
